Gene-level copy-number profile of tumor specimen TCGA-12-1096-01A from TCGA case TCGA-12-1096, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 55.6 years (20,321 days).
Specimen TCGA-12-1096-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.ef753f74-b65d-4a87-9d15-ffca9fc015ce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-1096-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f3284f4c-c547-40c3-9dfb-bf27cc745389

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 11,061; copy number 2: 43,255; copy number 3: 2,637; copy number 4: 2,806; copy number 15: 15; copy number 18: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-12-1096-01): tumor purity 0.48, ploidy 2.04, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:55,247,755–58,106,879, 14 genes (within-gene range 0–1): AC016822.1, AL355314.1, AL355314.2, MTRNR2L5, GAPDHP21, AC069545.1, ZWINT, AC010996.1, AC025039.1, MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 47 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:25,504,997–25,619,468, 3 genes, copy number 15 (within-gene range 3–15): AC133963.1, AC105290.1, RNU7-126P.
- chr4:54,065,239–54,845,470, 12 genes, copy number 15 (within-gene range 2–15): AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1.
- chr4:99,067,256–100,880,126, 32 genes, copy number 18: AC019131.2, ADH5, AP002026.1, ADH4, PCNAP1, ADH6, ADH1A, ADH1B, ADH1C, ADH7, AP001960.1, C4orf17, TRMT10A, MTTP, AC083902.1, C4orf54, DAPP1, AP001962.1, LAMTOR3, DNAJB14, AC097460.2, H2AZ1, H2AZ1-DT, AC097460.1, DYNLL1P6, DDIT4L, AP001961.1, EMCN, AC097459.1, LINC01216, LINC01217, LINC01218.

Autosomal genes at a single copy (total copy number 1): 8,640. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
